Somatic mutation profile of tumor specimen TCGA-OR-A5J4-01A (aliquot TCGA-OR-A5J4-01A-11D-A29I-10) from TCGA case TCGA-OR-A5J4, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 23.1 years (8,451 days).
Specimen TCGA-OR-A5J4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fa4e6606-4dbd-47cc-af68-0d1c034c697e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5J4-10A (Blood Derived Normal), aliquot TCGA-OR-A5J4-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20685494-8c80-47f5-a7e3-d0c9a28e5a0d

The open-access MAF lists 128 somatic variants for this specimen: 99 protein-altering or splice-affecting, 26 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 26, Nonsense Mutation 5, In Frame Del 4, Splice Site 3, Frame Shift Del 3, Intron 2, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A2ML1 | c.1441G>A p.A481T | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0.41); catalogued as COSV55290172; called by muse, mutect2, varscan2
- AKAP13 | c.8233C>A p.H2745N (on ENST00000394518 / NM_007200.5; = p.H2749N on NM_006738.6) | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV100774313, COSV63470370; called by muse, mutect2, varscan2
- ALK | c.3515+1G>A p.X1172_splice | Splice Site (SNP) | VAF 13/42 reads (31%) | catalogued as COSV66560042; called by muse, mutect2, varscan2
- CCDC88B | c.1925G>C p.R642T | Missense Mutation (SNP) | VAF 46/147 reads (31%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.261); catalogued as rs1041495704, COSV100105470; called by muse, mutect2, varscan2
- CDC73 | c.587C>A p.T196N | Missense Mutation (SNP) | VAF 72/192 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.788); catalogued as COSV66466691; called by muse, varscan2
- CHKB | c.523C>A p.H175N | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56418126; called by muse, mutect2, varscan2
- CHMP4C | c.530A>G p.N177S | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as COSV51926773; called by muse, mutect2, varscan2
- CLEC4C | c.511G>T p.G171C | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100665350; called by muse, mutect2, varscan2
- EGFLAM | c.1821G>C p.L607F | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100380254; called by muse, mutect2, varscan2
- FAM47C | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 28/407 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.307); catalogued as COSV63725008; called by muse, mutect2
- GPR82 | c.219C>G p.I73M | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV100220542; called by muse, mutect2, varscan2
- IFT43 | c.25G>C p.E9Q | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.673); catalogued as rs751183646, COSV53141942; called by muse, mutect2, varscan2
- IQSEC2 | c.1049C>G p.A350G (on ENST00000642864 / NM_001111125.3; = p.A145G on NM_015075.2) | Missense Mutation (SNP) | VAF 45/171 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM1511983; called by muse, mutect2, varscan2
- ISM2 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 48/179 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.314); catalogued as rs1456917277; called by muse, mutect2, varscan2
- KCND3 | c.1223G>A p.R408Q | Missense Mutation (SNP) | VAF 41/188 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as COSV56176007, COSV56184725; called by muse, mutect2, varscan2
- KCNH8 | c.2083G>T p.E695* | Nonsense Mutation (SNP) | VAF 48/129 reads (37%) | catalogued as COSV100109285; called by muse, mutect2, varscan2
- KLHL15 | c.1262G>T p.G421V | Missense Mutation (SNP) | VAF 66/257 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.228); catalogued as COSV60140850, COSV60141937; called by muse, mutect2, varscan2
- KMT2D | c.2260C>G p.P754A | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.125); catalogued as COSV56431319; called by muse, mutect2
- MCHR1 | c.73A>G p.T25A | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as rs147389509; called by muse, mutect2, varscan2
- MPDZ | c.1954G>T p.E652* | Nonsense Mutation (SNP) | VAF 20/102 reads (20%) | catalogued as COSV100064162; called by muse, mutect2, varscan2
- OR1K1 | c.59_61del p.T20del | In Frame Del (DEL) | VAF 38/180 reads (21%) | catalogued as rs1437356609; called by pindel, varscan2
- OR2AT4 | c.514G>C p.A172P | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.751); catalogued as COSV59407604; called by muse, mutect2, varscan2
- OR6C1 | c.590G>T p.G197V | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.35); catalogued as COSV65572770; called by muse, mutect2, varscan2
- PCDHB11 | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as rs781938950, COSV53377988; called by muse, mutect2, varscan2
- PHEX | c.937G>C p.D313H | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65075837; called by muse, varscan2
- PIGG | c.1657_1659del p.L553del (on ENST00000453061 / NM_001127178.3; = p.L545del on NM_017733.4) | In Frame Del (DEL) | VAF 54/216 reads (25%) | catalogued as rs774246524; called by pindel, varscan2
- PIGO | c.1255G>A p.A419T | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs879658217; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN11A | c.648C>G p.I216M | Missense Mutation (SNP) | VAF 77/160 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as rs1189932072; called by muse, mutect2, varscan2
- SLC20A2 | c.1335C>G p.I445M | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.977); catalogued as COSV60603117; called by muse, mutect2, varscan2
- SLC2A6 | c.1519C>T p.R507C | Missense Mutation (SNP) | VAF 6/131 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.333); catalogued as rs1554801617, COSV99390254; called by muse, mutect2
- SLC44A5 | c.1477C>T p.P493S | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.893); catalogued as rs779346781; called by muse, mutect2, varscan2
- SMC4 | c.3055G>C p.E1019Q | Missense Mutation (SNP) | VAF 49/204 reads (24%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.914); catalogued as rs750051763, COSV59087249; called by muse, mutect2, varscan2
- SNCAIP | c.1699C>T p.P567S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.895); catalogued as COSV54421185; called by muse, mutect2
- SPHK2 | c.909C>G p.N303K | Missense Mutation (SNP) | VAF 37/151 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV55334796; called by muse, mutect2, varscan2
- TMEM169 | c.56G>A p.G19D | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.003); catalogued as rs868489246; called by muse, mutect2, varscan2
- ZNF503 | c.234G>T p.K78N | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.505); catalogued as rs781432010; called by muse, mutect2, varscan2
- ADGRD1 | c.1899A>T p.Q633H | Missense Mutation (SNP) | VAF 65/81 reads (80%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- AFF3 | c.1928C>G p.S643C | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- AQP2 | c.242T>A p.V81D | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- BACH2 | c.1796C>T p.A599V | Missense Mutation (SNP) | VAF 36/227 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- BACH2 | c.1795G>A p.A599T | Missense Mutation (SNP) | VAF 36/227 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- BCAT1 | c.592A>C p.T198P | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- BRD1 | c.1368-1G>T p.X456_splice | Splice Site (SNP) | VAF 50/137 reads (36%) | called by muse, mutect2, varscan2
- C1orf226 | c.562A>G p.K188E | Missense Mutation (SNP) | VAF 93/227 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CARD6 | c.328del p.A110Qfs*13 | Frame Shift Del (DEL) | VAF 11/53 reads (21%) | called by mutect2, pindel, varscan2
- CLASP1 | c.1714A>T p.S572C | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- CNPY2 | c.223G>C p.E75Q | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL4A6 | c.783G>T p.K261N | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.755); called by muse, mutect2
- DPP3 | c.1895G>A p.G632E | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- DPYD | c.2633G>A p.S878N | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- DST | c.13094_13096del p.E4365del (on ENST00000361203 / NM_001374722.1; = p.E1953del on NM_015548.5) | In Frame Del (DEL) | VAF 9/33 reads (27%) | called by pindel, varscan2
- EML3 | c.991G>A p.D331N | Missense Mutation (SNP) | VAF 64/331 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- ETS2 | c.523G>T p.E175* | Nonsense Mutation (SNP) | VAF 24/63 reads (38%) | called by muse, mutect2, varscan2
- FAM47C | c.1546G>C p.E516Q | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- FBLN7 | c.1231G>C p.D411H | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- FILIP1 | c.3358C>G p.P1120A | Missense Mutation (SNP) | VAF 77/403 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- FKBPL | c.1001A>T p.K334M | Missense Mutation (SNP) | VAF 37/195 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- FLI1 | c.725C>A p.P242H | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FXR2 | c.662C>A p.T221K | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- GPAT2 | c.139G>C p.V47L | Missense Mutation (SNP) | VAF 118/617 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- HACE1 | c.2065A>C p.K689Q | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HOMER1 | c.906G>C p.E302D | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- HSD17B4 | c.1469G>A p.G490D (on ENST00000414835 / NM_001199291.3; = p.G465D on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HUWE1 | c.4357G>A p.E1453K | Missense Mutation (SNP) | VAF 51/214 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- IFNA8 | c.405G>A p.M135I | Missense Mutation (SNP) | VAF 45/204 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- IL18R1 | c.957G>T p.M319I | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITPR2 | c.2387T>G p.V796G | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); called by muse, mutect2, varscan2
- KIAA1755 | c.701C>A p.A234D | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KMT2A | c.2629G>C p.D877H | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- LILRA1 | c.35-2A>G p.X12_splice | Splice Site (SNP) | VAF 26/314 reads (8%) | called by muse, mutect2
- LRP1 | c.5708G>T p.G1903V | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAP1B | c.3814del p.L1272Wfs*6 | Frame Shift Del (DEL) | VAF 32/104 reads (31%) | called by mutect2, pindel, varscan2
- MAP1B | c.5999C>A p.T2000K | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- MAP3K15 | c.1803T>A p.D601E | Missense Mutation (SNP) | VAF 21/250 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.452); called by muse, mutect2
- MC1R | c.236G>A p.C79Y | Missense Mutation (SNP) | VAF 55/117 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MROH5 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- MYLK | c.3101C>A p.T1034N | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- MYO1F | c.1649G>A p.G550E | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MYO7B | c.1938C>A p.N646K | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT tolerated (0.68); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- NAB2 | c.1060_1061del p.S354Hfs*14 | Frame Shift Del (DEL) | VAF 40/180 reads (22%) | called by pindel, varscan2
- NOS3 | c.1308G>T p.K436N | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- OR6C1 | c.589G>T p.G197* | Nonsense Mutation (SNP) | VAF 32/122 reads (26%) | called by muse, mutect2, varscan2
- PARP12 | c.1274C>T p.A425V | Missense Mutation (SNP) | VAF 46/64 reads (72%) | SIFT tolerated (0.06); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- PCDHGA5 | c.2270T>G p.V757G | Missense Mutation (SNP) | VAF 43/160 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.912); called by muse, varscan2
- PIKFYVE | c.5639C>G p.P1880R | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PNLIPRP1 | c.392C>A p.A131D | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- POLR1A | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RAD1 | c.293C>G p.S98* | Nonsense Mutation (SNP) | VAF 48/209 reads (23%) | called by muse, mutect2, varscan2
- RAX | c.430dup p.T144Nfs*7 | Frame Shift Ins (INS) | VAF 50/148 reads (34%) | called by mutect2, pindel, varscan2
- RBM14 | c.226C>G p.L76V | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- RET | c.1274T>C p.V425A | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.497); called by muse, mutect2
- SH3D19 | c.2364G>C p.Q788H | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- SLA2 | c.662A>G p.D221G | Missense Mutation (SNP) | VAF 31/177 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- SNW1 | c.565A>T p.N189Y | Missense Mutation (SNP) | VAF 37/52 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SPHK1 | c.922_924del p.K308del (on ENST00000392496 / NM_001355139.2; = p.K322del on NM_021972.4) | In Frame Del (DEL) | VAF 64/145 reads (44%) | called by mutect2, varscan2
- SUPT16H | c.284A>G p.E95G | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.427); called by muse, mutect2, varscan2
- TMC7 | c.1408G>C p.D470H | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- TRIM39 | c.730G>C p.A244P | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- TRIOBP | c.4663C>A p.P1555T | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.062); called by muse, varscan2
- ATAD2B | c.1353C>G p.A451= | Silent (SNP) | VAF 45/91 reads (49%) | catalogued as rs866028800; called by muse, mutect2, varscan2
- ATP13A5 | c.2089T>C p.L697= | Silent (SNP) | VAF 20/64 reads (31%) | called by muse, mutect2, varscan2
- CHMP2B | c.207G>A p.R69= | Silent (SNP) | VAF 97/275 reads (35%) | called by muse, mutect2, varscan2
- ELOVL7 | c.189A>G p.E63= | Silent (SNP) | VAF 56/203 reads (28%) | called by muse, mutect2, varscan2
- EPB41L1 | c.891C>T p.D297= | Silent (SNP) | VAF 39/165 reads (24%) | called by muse, mutect2, varscan2
- FANK1 | c.675G>A p.V225= | Silent (SNP) | VAF 46/147 reads (31%) | called by muse, mutect2, varscan2
- FXR1 | c.1440T>A p.L480= | Silent (SNP) | VAF 36/220 reads (16%) | called by muse, varscan2
- GPR161 | c.1104G>C p.L368= | Silent (SNP) | VAF 25/59 reads (42%) | called by muse, mutect2, varscan2
- HMBS | c.738C>T p.R246= | Silent (SNP) | VAF 6/73 reads (8%) | called by muse, mutect2
- KCNA7 | c.1302C>T p.D434= | Silent (SNP) | VAF 33/178 reads (19%) | catalogued as rs145070146; called by muse, mutect2, varscan2
- MAN2A2 | c.1107A>G p.Q369= | Silent (SNP) | VAF 27/58 reads (47%) | catalogued as rs754573425; called by muse, mutect2, varscan2
- MIPOL1 | c.120G>T p.R40= | Silent (SNP) | VAF 64/189 reads (34%) | called by muse, mutect2, varscan2
- NEDD9 | c.2247C>A p.V749= | Silent (SNP) | VAF 67/188 reads (36%) | called by muse, mutect2, varscan2
- OCRL | c.2376C>A p.L792= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV63980738; called by muse, mutect2, varscan2
- OGDH | c.912C>T p.Y304= | Silent (SNP) | VAF 60/162 reads (37%) | catalogued as COSV56057888; called by muse, mutect2, varscan2
- OR52N1 | c.333G>C p.G111= | Silent (SNP) | VAF 51/72 reads (71%) | catalogued as COSV57692959; called by muse, mutect2, varscan2
- PAEP | c.13C>T p.L5= | Silent (SNP) | VAF 41/185 reads (22%) | called by muse, mutect2, varscan2
- PCSK5 | c.3306G>A p.E1102= | Silent (SNP) | VAF 77/250 reads (31%) | catalogued as COSV101377618, COSV70446608; called by muse, mutect2, varscan2
- PGK2 | c.654A>G p.A218= | Silent (SNP) | VAF 66/331 reads (20%) | called by muse, mutect2, varscan2
- SH3GL2 | c.933T>C p.F311= | Silent (SNP) | VAF 12/306 reads (4%) | called by muse, mutect2
- SLC6A15 | c.1761T>A p.A587= | Silent (SNP) | VAF 139/296 reads (47%) | called by muse, mutect2, varscan2
- SPTA1 | c.1407T>C p.H469= | Silent (SNP) | VAF 21/69 reads (30%) | called by muse, mutect2, varscan2
- USH2A | c.7722A>G p.L2574= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as COSV56365309; called by muse, mutect2, varscan2
- YLPM1 | c.3522A>G p.G1174= | Silent (SNP) | VAF 29/107 reads (27%) | called by muse, mutect2, varscan2
- ZNF704 | c.1236C>T p.D412= | Silent (SNP) | VAF 23/103 reads (22%) | called by muse, mutect2, varscan2
- ZNF770 | c.235C>T p.L79= | Silent (SNP) | VAF 18/36 reads (50%) | called by muse, mutect2, varscan2
- CACNA1C | c.1217+310A>G | Intron (SNP) | VAF 44/226 reads (19%) | called by muse, mutect2, varscan2
- FAM110B | c.*1G>C | 3'UTR (SNP) | VAF 64/260 reads (25%) | called by muse, mutect2, varscan2
- TTN | c.10303+2281C>A | Intron (SNP) | VAF 7/96 reads (7%) | called by muse, mutect2
